Somatic mutation profile of tumor specimen TCGA-D3-A1Q3-06A (aliquot TCGA-D3-A1Q3-06A-11D-A196-08) from TCGA case TCGA-D3-A1Q3, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 65.3 years (23,852 days).
Specimen TCGA-D3-A1Q3-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89f5375c-57b6-4c1a-a8d5-cf192a9c3c0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A1Q3-10A (Blood Derived Normal), aliquot TCGA-D3-A1Q3-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c0189bf-db6c-4787-b97c-83505c585614

The open-access MAF lists 41 somatic variants for this specimen: 29 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 11, Frame Shift Del 2, Splice Region 2, Intron 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1924A>G p.K642E | Missense Mutation (SNP) | VAF 357/434 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913512, CM002803, COSV55387507, COSV55411978; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.3884T>C p.L1295S | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67017296; called by muse, mutect2, varscan2
- AL592490.1 | c.1580A>T p.D527V | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69426673; called by muse, varscan2
- BSN | c.6617T>C p.L2206P | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56520755; called by muse, mutect2, varscan2
- C16orf78 | c.72A>C p.E24D | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV54556863; called by muse, mutect2, varscan2
- CFAP52 | c.879C>G p.I293M | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV55345938; called by muse, mutect2, varscan2
- DUXA | c.441T>A p.I147= | Splice Region (SNP) | VAF 9/48 reads (19%) | catalogued as COSV73729751; called by mutect2, varscan2
- ELAPOR1 | c.1765C>T p.R589C | Missense Mutation (SNP) | VAF 120/428 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs760194931, COSV64040616; called by muse, varscan2
- ESD | c.8T>C p.L3S | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV66340447; called by muse, mutect2, varscan2
- FLT1 | c.871A>C p.I291L | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV56730913; called by muse, mutect2, varscan2
- GCOM1 | c.410C>G p.S137* | Nonsense Mutation (SNP) | VAF 13/136 reads (10%) | catalogued as COSV51092279, COSV51100482; called by muse, mutect2
- HEPHL1 | c.566A>G p.H189R | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59892854; called by muse, mutect2, varscan2
- HS3ST3A1 | c.1178A>C p.K393T | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52376169; called by muse, mutect2, varscan2
- HSPA6 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59061394; called by mutect2, varscan2
- IGFL3 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as rs892112847, COSV58242876; called by muse, mutect2
- KCNMA1 | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV54256955; called by muse, mutect2, varscan2
- MAGI2 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1470111212, COSV62670057; called by muse, varscan2
- PARD3 | c.404-1G>A p.X135_splice | Splice Site (SNP) | VAF 30/109 reads (28%) | catalogued as COSV60746922, COSV60752533; called by muse, mutect2, varscan2
- RALGAPA2 | c.5208G>A p.K1736= | Splice Region (SNP) | VAF 19/46 reads (41%) | catalogued as COSV52500879; called by muse, mutect2, varscan2
- RBM6 | c.3014G>A p.R1005Q | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs746681545, COSV56484074, COSV56484132; called by mutect2, varscan2
- SEMA6B | c.1340T>C p.L447P | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100014603, COSV56704333; called by muse, mutect2, varscan2
- SLC16A1 | c.356T>A p.I119N | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100855963; called by muse, mutect2, varscan2
- TLE4 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 56/153 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV54634125; called by muse, mutect2, varscan2
- TLL1 | c.563A>G p.H188R | Missense Mutation (SNP) | VAF 56/167 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV50293708; called by muse, mutect2, varscan2
- TPTE | c.833A>G p.H278R (on ENST00000618007 / NM_199261.4; = p.H260R on NM_199259.4) | Missense Mutation (SNP) | VAF 21/205 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as rs749002591; called by muse, mutect2, varscan2
- ZBTB20 | c.1960C>T p.R654C (on ENST00000474710 / NM_001164342.2; = p.R581C on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61849776; called by mutect2, varscan2
- ZNF721 | c.2349C>G p.S783R (on ENST00000338977; = p.S795R on NM_133474.4) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.899); catalogued as COSV59093713; called by muse, varscan2
- AHCTF1 | c.4380_4381del p.K1460Nfs*14 (on ENST00000366508; = p.K1434Nfs*14 on NM_015446.5) | Frame Shift Del (DEL) | VAF 28/110 reads (25%) | called by mutect2, pindel, varscan2
- SLITRK3 | c.2337del p.P780Qfs*13 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- ALDOC | c.591C>T p.H197= | Silent (SNP) | VAF 54/156 reads (35%) | catalogued as rs564709825, COSV52024999; called by mutect2, varscan2
- ELK4 | c.1179T>C p.G393= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV56985210; called by muse, mutect2, varscan2
- FAT4 | c.9291T>C p.S3097= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV58691048; called by muse, mutect2, varscan2
- INAVA | c.498T>A p.V166= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV66256935; called by muse, varscan2
- MYH1 | c.2247C>T p.L749= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs887546231, COSV56850622, COSV99875468; called by muse, mutect2, varscan2
- NUP37 | c.129T>C p.Y43= | Silent (SNP) | VAF 28/153 reads (18%) | catalogued as rs763155034, COSV51838169; called by muse, varscan2
- PI4KA | c.4986G>A p.R1662= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs1285854914, COSV55413867; called by muse, mutect2
- SMCHD1 | c.4425C>T p.N1475= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs750987658, COSV55259833; called by mutect2, varscan2
- TDRD5 | c.2190G>T p.L730= | Silent (SNP) | VAF 36/125 reads (29%) | catalogued as COSV54238722, COSV54244707, COSV54250926; called by muse, mutect2, varscan2
- TTF1 | c.1686T>C p.S562= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV57504924; called by muse, mutect2, varscan2
- ZNF711 | c.1629A>G p.A543= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV52155808; called by muse, mutect2
- GBA3 | c.59-8360A>C | Intron (SNP) | VAF 37/234 reads (16%) | catalogued as COSV69742586; called by muse, mutect2, varscan2
